Surgical pathology report (de-identified scan), TCGA case TCGA-SW-A7EB, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Global Bioclinical-Moldova, specimen TCGA-SW-A7EB-01A (Primary Tumor).

Final Pathology Template

Final Pathology Report Information

- 1.1 Tissue Specimen ID Code:
- 1.2 Date of Excision:
- 1.3 Tumor Location (*anatomic site*): **Stomach, Antrum**
- 1.4 Tumor Size: **3.0x 4.0 (cm)**
- 1.5 Lymph Node Status:
- 1.5.1 Number Nodes Examined: **5**
- 1.5.2 Number Nodes Positive: **3**
- 1.5.3 Lymph Node Locations (Involved Nodes): **2 greater curvature, 3 lesser curvature**
- 1.6 Metastasis:
- 1.6.1 Metastasis Present: ☐ Yes ☒ No ☐ Unknown
- 1.6.2 Number of Mets: _____
- 1.6.3 Site(s) Of Metastasis: _____
- 1.7 ICD-9 Code for Specimen Diagnosis: **C 16.3**
- 1.8 Final Pathology Details:
(Please supply de-identified copy of original language final pathology report in addition to information below)

1.8.1 Macroscopic Description: Surgical specimen of stomach, measuring 12 cm in combination with greater omentum. At 5.0 cm from the distal resection margin, ulcerative formation with regular borders 3.0 x 4.0cm in dimension, infiltrating the 1/2 gastric wall. Greater omentum is intact. 5 lymph nodes (2 - greater curvatures, 3 - lessen curvature).

1.8.2 Microscopic Description: Moderately differentiated adenocarcinoma of stomach, mucinous type, ulcerated, with areas hyalinosis and lymphoid. Tumor invades all wall of the stomach. Margins resection is intact. Greater omentum is intact. Lymph nodes status positive: greater curvature (2 from 2) and lesser curvature (1 form 3).

1.8.3 Comment (if applicable):

1.8.4 Clinical Diagnosis: **Gastric cancer of antrum**

1.8.5 Stage: **T3 N2 M0, st. IIIA**

PROPRIETARY AND CONFIDENTIAL

Source: NCI Genomic Data Commons file b96dfe5d-cc32-4d31-b8bf-35003175cb71 (TCGA-SW-A7EB.096769DA-F6AE-44A3-8002-9694414D4228.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).